Somatic mutation profile of tumor specimen TCGA-ER-A3ES-06A (aliquot TCGA-ER-A3ES-06A-11D-A20D-08) from TCGA case TCGA-ER-A3ES, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.5 years (16,605 days).
Specimen TCGA-ER-A3ES-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d18ccec-87d9-4744-8963-67c8fbb4064c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A3ES-10A (Blood Derived Normal), aliquot TCGA-ER-A3ES-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f806b8b6-beda-44a4-8600-4ede8c4bde6a

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 29/42 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT3 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as rs1349060333, COSV56753050; called by muse, mutect2, varscan2
- CCDC87 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 181/225 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV59579250; called by muse, mutect2, varscan2
- CDH23 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.279); catalogued as rs200328570; ClinVar: uncertain significance; called by muse, mutect2
- MMP11 | c.1039T>G p.F347V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53156495; called by muse, mutect2, varscan2
- MYO10 | c.3495del p.R1166Vfs*19 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as COSV57031696; called by mutect2, pindel, varscan2
- NADSYN1 | c.1656G>C p.Q552H | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV59812535; called by muse, mutect2, varscan2
- PCDHB5 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50653874; called by muse, mutect2, varscan2
- PNP | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV64091980; called by muse, mutect2, varscan2
- SEMA4G | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751695050, COSV52968722; called by muse, mutect2, varscan2
- SLC22A11 | c.768G>T p.R256S | Missense Mutation (SNP) | VAF 267/686 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as COSV57253485; called by muse, mutect2, varscan2
- SLC24A5 | c.369A>C p.L123F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV58317774; called by muse, mutect2, varscan2
- SNAI2 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.459); catalogued as COSV50079255; called by muse, mutect2, varscan2
- SRGAP2 | c.1513C>G p.L505V (on ENST00000624873 / NM_001170637.4; = p.L506V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/221 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); catalogued as COSV55338223; called by muse, mutect2, varscan2
- ZFAND4 | c.1028A>C p.H343P | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60859362; called by muse, mutect2, varscan2
- ZFP30 | c.80A>C p.Q27P | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV63622684; called by muse, mutect2, varscan2
- VPS53 | c.1524del p.Y508* (on ENST00000571805 / NM_001366253.2; = p.Y479* on NM_018289.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | called by mutect2, pindel, varscan2
- ACTL7B | c.435C>T p.H145= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs149121708, COSV65926845; called by muse, mutect2, varscan2
- FBLN5 | c.447C>T p.G149= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as rs1384736774, COSV50904336; called by muse, mutect2, varscan2
- HK3 | c.1347G>A p.P449= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as rs143340857; called by muse, mutect2, varscan2
- MTMR11 | c.993T>A p.S331= (on ENST00000439741 / NM_001145862.2; = p.S259= on NM_181873.3) | Silent (SNP) | VAF 125/242 reads (52%) | catalogued as COSV54965639; called by muse, mutect2, varscan2
